Somatic mutation profile of tumor specimen 0DM1KA from CCDI case PBCADZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 18.0 years (6,564 days).
Specimen 0DM1KA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cc8fcd7-1154-4f41-8e83-6c13bc0f76da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM1JH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87709414-619d-4352-af79-ebd8f9e5e6b8

The open-access MAF lists 23 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 7, Splice Site 2, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 49/232 reads (21%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 148/296 reads (50%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AL645922.1 | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 92/372 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV54960083; called by muse, mutect2, varscan2
- KLHL26 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 73/277 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.056); catalogued as rs867504482; called by muse, mutect2, varscan2
- LTBP1 | c.4400-2A>T p.X1467_splice (on ENST00000404816 / NM_206943.4; = p.X1141_splice on NM_000627.4) | Splice Site (SNP) | VAF 62/240 reads (26%) | catalogued as rs1287153803; called by muse, mutect2, varscan2
- NLRP10 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 54/517 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs753840685, COSV60780204; called by muse, mutect2, varscan2
- OBSL1 | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 84/361 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs1424473557, COSV54709706; called by muse, mutect2, varscan2
- PGGHG | c.1759G>A p.G587S | Missense Mutation (SNP) | VAF 88/344 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs866797218; called by muse, mutect2, varscan2
- RABL3 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 89/380 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.269); catalogued as rs144478835; called by muse, mutect2, varscan2
- TKT | c.1519G>A p.G507R | Missense Mutation (SNP) | VAF 104/431 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1406351387; called by muse, mutect2, varscan2
- UBR5 | c.5795A>G p.H1932R | Missense Mutation (SNP) | VAF 114/578 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV55297718; called by muse, mutect2, varscan2
- CUL9 | c.6618G>A p.M2206I | Missense Mutation (SNP) | VAF 88/373 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PAPPA2 | c.2069G>A p.S690N | Missense Mutation (SNP) | VAF 102/364 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RALGAPA2 | c.2901+1G>C p.X967_splice | Splice Site (SNP) | VAF 75/314 reads (24%) | called by muse, mutect2, varscan2
- BRF1 | c.42C>A p.I14= | Silent (SNP) | VAF 81/358 reads (23%) | called by muse, mutect2, varscan2
- EPG5 | c.4545G>A p.T1515= | Silent (SNP) | VAF 91/405 reads (22%) | catalogued as rs768482660, COSV56351084; called by muse, mutect2, varscan2
- FSIP2 | c.4566A>G p.S1522= | Silent (SNP) | VAF 107/457 reads (23%) | called by muse, mutect2, varscan2
- PLEC | c.10326C>T p.F3442= (on ENST00000322810 / NM_201380.4; = p.F3332= on NM_000445.5) | Silent (SNP) | VAF 66/320 reads (21%) | catalogued as rs1554679848; called by muse, mutect2, varscan2
- RBM19 | c.1548A>T p.T516= | Silent (SNP) | VAF 76/303 reads (25%) | called by muse, mutect2, varscan2
- SCN5A | c.5037C>T p.F1679= (on ENST00000333535 / NM_198056.3; = p.F1678= on NM_000335.5) | Silent (SNP) | VAF 125/515 reads (24%) | catalogued as rs867169736, COSV61117166; ClinVar: likely benign; called by muse, mutect2, varscan2
- SSX7 | c.486T>C p.H162= | Silent (SNP) | VAF 58/247 reads (23%) | called by muse, mutect2, varscan2
- RARS1 | c.579+9A>G | Intron (SNP) | VAF 60/220 reads (27%) | called by muse, mutect2, varscan2
- ZNF75A | c.-316+2887A>G | Intron (SNP) | VAF 30/263 reads (11%) | called by muse, mutect2, varscan2
